Somatic mutation profile of tumor specimen C3N-01167-01 (aliquot CPT0087890010) from CPTAC case C3N-01167, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 77.1 years (28,149 days).
Specimen C3N-01167-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e9bdf30-ce87-4a00-9e12-7660859dbbea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01167-31 (Blood Derived Normal), aliquot CPT0087930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a1c9fe2-f12c-4be2-ab31-07c39f4e9136

The open-access MAF lists 61 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 16, Intron 4, Frame Shift Del 3, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 120/376 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100313066; called by muse, mutect2, varscan2
- ADGRD1 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 137/451 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs200971352, COSV55440249; called by muse, mutect2, varscan2
- COL5A1 | c.5263G>A p.A1755T | Missense Mutation (SNP) | VAF 200/724 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.245); catalogued as rs776748227, COSV65664867, COSV65666442; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CYLC1 | c.1840C>A p.P614T | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV100254500; called by muse, mutect2, varscan2
- DCC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267605206, COSV59087112; called by muse, mutect2, varscan2
- FAM214A | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs201191117; called by muse, mutect2, varscan2
- FAT2 | c.7808C>T p.P2603L | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs372313673; called by muse, mutect2, varscan2
- ITGAM | c.1615G>A p.V539M (on ENST00000648685 / NM_001145808.2; = p.V538M on NM_000632.4) | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs1235616243; called by muse, mutect2, varscan2
- KRTAP4-3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 129/500 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs1442367115, COSV101194142; called by muse, varscan2
- MADD | c.2503G>A p.V835I | Missense Mutation (SNP) | VAF 131/350 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs760678538; called by muse, mutect2, varscan2
- MAS1L | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs755412096; called by muse, mutect2, varscan2
- MRGPRE | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs994216531; called by muse, mutect2, varscan2
- MYO7B | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs755921738, COSV67344428; called by muse, mutect2, varscan2
- OPRM1 | c.786G>C p.K262N | Missense Mutation (SNP) | VAF 124/457 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1245821772; called by muse, mutect2, varscan2
- PCDH18 | c.3397C>T p.R1133C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1386245070, COSV61272057; called by muse, mutect2, varscan2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 95/539 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2, varscan2
- PCDHGA5 | c.1676C>T p.T559M | Missense Mutation (SNP) | VAF 190/583 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs760966863, COSV54003473; called by muse, mutect2, varscan2
- PHF24 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 39/538 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs372641183; called by muse, mutect2
- PRR33 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1382961147, COSV100289042; called by muse, mutect2, varscan2
- RYR1 | c.5861G>A p.R1954H | Missense Mutation (SNP) | VAF 240/965 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775643457; called by muse, mutect2, varscan2
- SLC30A8 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141202988, COSV69969422; called by muse, mutect2, varscan2
- SLCO6A1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV65808025; called by muse, mutect2, varscan2
- SRCAP | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.727); catalogued as rs993440316; called by muse, mutect2, varscan2
- STK32B | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 78/379 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745729733, COSV51481411; called by muse, mutect2, varscan2
- TRIM45 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 62/674 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV56713692, COSV56714109; called by muse, mutect2
- TTN | c.54889G>A p.A18297T (on ENST00000591111; = p.A10873T on NM_003319.4) | Missense Mutation (SNP) | VAF 104/439 reads (24%) | PolyPhen probably damaging (0.915); catalogued as rs755204306, COSV60146923; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBA3C | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 147/630 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs572405672, COSV68029607; called by muse, mutect2, varscan2
- CPA5 | c.1252C>G p.Q418E | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREBRF | c.228T>A p.D76E | Missense Mutation (SNP) | VAF 64/365 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FGD6 | c.2560G>C p.E854Q | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- IFNL1 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LDOC1 | c.105C>A p.C35* | Nonsense Mutation (SNP) | VAF 124/480 reads (26%) | called by muse, mutect2, varscan2
- OR13C3 | c.725T>A p.M242K | Missense Mutation (SNP) | VAF 125/487 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAB3GAP1 | c.2591del p.K864Rfs*8 | Frame Shift Del (DEL) | VAF 101/745 reads (14%) | called by mutect2, varscan2
- RUNX2 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 156/445 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SMAD4 | c.1264_1280del p.P422* | Frame Shift Del (DEL) | VAF 71/389 reads (18%) | called by pindel, varscan2
- TENM4 | c.5684G>A p.G1895D | Missense Mutation (SNP) | VAF 176/534 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.945_946del p.Q317Afs*19 | Frame Shift Del (DEL) | VAF 221/666 reads (33%) | called by pindel, varscan2
- TSPAN32 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 76/412 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- ATAD2B | c.1287T>C p.F429= | Silent (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- BEND4 | c.826C>T p.L276= | Silent (SNP) | VAF 47/331 reads (14%) | called by muse, mutect2, varscan2
- CCDC110 | c.2064T>C p.S688= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs1370736606; called by muse, mutect2, varscan2
- CCM2L | c.1566G>A p.A522= | Silent (SNP) | VAF 42/286 reads (15%) | called by muse, mutect2, varscan2
- CHIT1 | c.168C>T p.Y56= | Silent (SNP) | VAF 181/1339 reads (14%) | catalogued as rs149551689; called by muse, mutect2, varscan2
- CPXM2 | c.1215G>A p.A405= | Silent (SNP) | VAF 98/202 reads (49%) | catalogued as rs1427160202; called by muse, mutect2, varscan2
- CRAMP1 | c.1194G>A p.L398= | Silent (SNP) | VAF 111/302 reads (37%) | called by muse, mutect2, varscan2
- DACT1 | c.2292C>T p.G764= | Silent (SNP) | VAF 35/253 reads (14%) | catalogued as rs140041218; called by muse, mutect2, varscan2
- DNAH1 | c.6372C>T p.R2124= | Silent (SNP) | VAF 136/376 reads (36%) | called by muse, mutect2, varscan2
- IMPG2 | c.3528C>T p.P1176= | Silent (SNP) | VAF 136/398 reads (34%) | called by muse, mutect2, varscan2
- OR11L1 | c.834C>T p.Y278= | Silent (SNP) | VAF 34/656 reads (5%) | called by muse, mutect2
- PIK3R6 | c.252C>T p.L84= | Silent (SNP) | VAF 69/152 reads (45%) | catalogued as rs373458593; called by muse, mutect2, varscan2
- TUT1 | c.888C>T p.S296= | Silent (SNP) | VAF 32/179 reads (18%) | catalogued as rs376134412; called by muse, mutect2, varscan2
- WDR87 | c.3732C>T p.D1244= | Silent (SNP) | VAF 100/392 reads (26%) | catalogued as rs544768229; called by muse, mutect2, varscan2
- ZNF516 | c.408C>T p.G136= | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as rs773122359, COSV71587445; called by muse, mutect2, varscan2
- ZRANB3 | c.723T>C p.N241= | Silent (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- CPNE2 | c.-36+1284C>T | Intron (SNP) | VAF 79/296 reads (27%) | catalogued as rs778148063, COSV51960770, COSV99321214; called by muse, mutect2, varscan2
- GABRE | c.1137+109G>A | Intron (SNP) | VAF 51/471 reads (11%) | called by muse, mutect2, varscan2
- SDHAF4 | c.-11G>T | 5'UTR (SNP) | VAF 75/225 reads (33%) | catalogued as rs1483744491; called by muse, mutect2, varscan2
- TRPA1 | c.1530-51G>A | Intron (SNP) | VAF 44/459 reads (10%) | catalogued as rs548914818; called by muse, mutect2
- TTN | c.10360+2985C>G | Intron (SNP) | VAF 124/489 reads (25%) | called by muse, mutect2, varscan2
